Somatic mutation profile of tumor specimen 0DQ55N from CCDI case PBCENC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Mucosa of lip, NOS; Age at diagnosis: 1.2 years (456 days).
Specimen 0DQ55N: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4b40798-b6fc-4a27-870d-86369d90a367.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQ55W (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68d52461-96aa-4253-a9bb-467816181366

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 3, Silent 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEP120 | c.1048G>C p.E350Q | Missense Mutation (SNP) | VAF 18/632 reads (3%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 34/1144 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- MUC3A | c.5599T>C p.S1867P | Missense Mutation (SNP) | VAF 39/287 reads (14%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2, varscan2
- SUMO2 | c.13_14dup p.P6Sfs*16 | Frame Shift Ins (INS) | VAF 114/258 reads (44%) | called by mutect2, varscan2
- ANKRD52 | c.2229C>T p.H743= | Silent (SNP) | VAF 139/327 reads (43%) | catalogued as rs1455347837, COSV57283888; called by muse, mutect2, varscan2
- GABBR2 | c.1545G>A p.S515= | Silent (SNP) | VAF 161/367 reads (44%) | catalogued as rs374493679, COSV52298550; called by muse, mutect2, varscan2
- NEDD9 | c.1731G>A p.T577= | Silent (SNP) | VAF 171/354 reads (48%) | catalogued as rs565770462, COSV65219938; called by muse, mutect2, varscan2
